Somatic mutation profile of tumor specimen 0DJE3A from CCDI case PBBVDC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Oropharynx, NOS; Age at diagnosis: 7.8 years (2,851 days).
Specimen 0DJE3A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 233491eb-2ed6-4a2f-a673-3ae127d932a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJE3F (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/731a5aa7-356f-44cb-90eb-d13bbe9da8eb

The open-access MAF lists 24 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 6, Silent 3, RNA 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH6 | c.8072G>A p.R2691Q | Missense Mutation (SNP) | VAF 66/624 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs904549451; called by muse, mutect2, varscan2
- ITSN1 | c.4763G>A p.R1588H | Missense Mutation (SNP) | VAF 24/617 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1164637837; called by muse, mutect2
- PTCHD4 | c.1631G>A p.G544E | Missense Mutation (SNP) | VAF 103/822 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as rs1168489062; called by muse, mutect2, varscan2
- SYNGAP1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1455672655; called by muse, mutect2, varscan2
- TOGARAM1 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 115/813 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368444580; called by muse, mutect2, varscan2
- DHCR24 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 48/1022 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABPB2 | c.77T>C p.M26T | Missense Mutation (SNP) | VAF 32/1012 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC4C | c.284G>A p.S95N | Missense Mutation (SNP) | VAF 84/822 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MYH7 | c.841A>G p.R281G | Missense Mutation (SNP) | VAF 76/1308 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); called by muse, mutect2
- PPP2R3A | c.1685C>A p.S562* | Nonsense Mutation (SNP) | VAF 44/1155 reads (4%) | called by muse, mutect2
- PTCHD4 | c.1630G>A p.G544R | Missense Mutation (SNP) | VAF 102/825 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- TASOR | c.722T>C p.F241S | Missense Mutation (SNP) | VAF 192/1087 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDHR2 | c.1776C>A p.I592= | Silent (SNP) | VAF 24/694 reads (3%) | catalogued as COSV56138727; called by muse, mutect2
- KIF26B | c.1146G>A p.V382= | Silent (SNP) | VAF 127/728 reads (17%) | catalogued as COSV69458561; called by muse, mutect2, varscan2
- SLC7A1 | c.420A>C p.I140= | Silent (SNP) | VAF 82/960 reads (9%) | called by muse, mutect2
- AMOTL2 | c.*94C>T | 3'UTR (SNP) | VAF 25/120 reads (21%) | catalogued as rs1467282352; called by muse, mutect2
- C7orf66 | n.187A>G | RNA (SNP) | VAF 58/2292 reads (3%) | called by muse, mutect2
- COP1 | c.2134-84A>G | Intron (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- IGSF6 | c.427+28C>T | Intron (SNP) | VAF 38/275 reads (14%) | catalogued as rs1196551397; called by muse, mutect2, varscan2
- NPAP1L | n.888A>G | RNA (SNP) | VAF 27/666 reads (4%) | catalogued as COSV73747295; called by muse, mutect2
- NSFL1C | c.786-60T>A | Intron (SNP) | VAF 8/232 reads (3%) | called by muse, mutect2
- PLCB2 | c.582+380G>T | Intron (SNP) | VAF 108/544 reads (20%) | catalogued as rs777575668; called by muse, mutect2, varscan2
- SMCO2 | c.601-99G>T | Intron (SNP) | VAF 14/89 reads (16%) | called by mutect2, varscan2
- USP40 | c.2381-58G>T | Intron (SNP) | VAF 21/486 reads (4%) | called by muse, mutect2
